Somatic mutation profile of tumor specimen MP2PRT-PATHZF-TMP1-A (aliquot MP2PRT-PATHZF-TMP1-A-1-0-D-A81O-36) from MP2PRT case MP2PRT-PATHZF, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 5.6 years (2,037 days).
Specimen MP2PRT-PATHZF-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) eb8e18a5-db2b-40c5-807f-da1f3fbabebe.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PATHZF-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PATHZF-NB1-A-1-0-D-A81O-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d794e54e-3d03-4cd0-a4e9-f000693d2ce8

The open-access MAF lists 12 somatic variants for this specimen: 10 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 10, Silent 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- MTOR | c.4379T>C p.L1460P | Missense Mutation (SNP) | VAF 17/523 reads (3%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.352); catalogued as rs1057519779, COSV63868845; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2
- CAMTA2 | c.2080C>T p.R694C | Missense Mutation (SNP) | VAF 110/492 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.65); catalogued as rs200231791; called by muse, mutect2, varscan2
- LONRF2 | c.1000G>T p.A334S | Missense Mutation (SNP) | VAF 118/366 reads (32%) | SIFT tolerated (0.5); PolyPhen benign (0.021); catalogued as rs1359983931; called by muse, mutect2, varscan2
- MAGEB6 | c.566G>T p.R189L | Missense Mutation (SNP) | VAF 183/531 reads (34%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as COSV100983883, COSV66872315; called by muse, mutect2, varscan2
- MED12 | c.6431A>G p.Q2144R | Missense Mutation (SNP) | VAF 142/502 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.775); catalogued as COSV99048869; called by muse, mutect2, varscan2
- MROH2A | c.1742G>A p.R581H | Missense Mutation (SNP) | VAF 152/449 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.455); catalogued as rs182734868, COSV67680971; called by muse, mutect2, varscan2
- NCKAP1 | c.1160G>A p.R387H | Missense Mutation (SNP) | VAF 116/312 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs370443899; called by muse, mutect2, varscan2
- SCARA5 | c.473C>T p.A158V | Missense Mutation (SNP) | VAF 162/747 reads (22%) | SIFT tolerated (0.05); PolyPhen benign (0.062); catalogued as rs776277770, COSV57282006; called by muse, mutect2, varscan2
- H2AC11 | c.323T>A p.V108D | Missense Mutation (SNP) | VAF 136/355 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- OR13H1 | c.371T>C p.V124A | Missense Mutation (SNP) | VAF 214/537 reads (40%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.938); called by muse, mutect2, varscan2
- PPP1R26 | c.15C>T p.N5= | Silent (SNP) | VAF 83/247 reads (34%) | catalogued as rs368677537, COSV63355101; called by muse, mutect2, varscan2
- WDR81 | c.4791C>T p.S1597= (on ENST00000409644 / NM_001163809.2; = p.S546= on NM_152348.4) | Silent (SNP) | VAF 36/916 reads (4%) | catalogued as rs551236660; called by muse, mutect2
